Somatic mutation profile of tumor specimen TCGA-51-4081-01A (aliquot TCGA-51-4081-01A-01D-1458-08) from TCGA case TCGA-51-4081, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 55.5 years (20,261 days).
Specimen TCGA-51-4081-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 196f02ae-54ab-4618-90a8-b9ce43af75f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-51-4081-11A (Solid Tissue Normal), aliquot TCGA-51-4081-11A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98376d71-594b-4fbc-a497-f21a1eca9c2e

The open-access MAF lists 209 somatic variants for this specimen: 164 protein-altering or splice-affecting, 44 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 44, Nonsense Mutation 9, Frame Shift Del 5, Splice Site 5, Frame Shift Ins 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1435C>T p.R479* (on ENST00000281708 / NM_001349798.2; = p.R399* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 36/98 reads (37%) | hotspot (GDC flag); catalogued as COSV55894141, COSV55894999, COSV55908957; called by muse, mutect2, varscan2
- GPI | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs137853583, CM930354, COSV62893986; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 43/75 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960047; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 62/146 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762846821, CM951223, COSV52667239, COSV52783646, COSV53625267; called by muse, mutect2, varscan2
- ABCB9 | c.119A>T p.H40L | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV54891811; called by muse, mutect2, varscan2
- AC131160.1 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 104/368 reads (28%) | catalogued as COSV57700671; called by muse, mutect2, varscan2
- ACP6 | c.349-1G>A p.X117_splice | Splice Site (SNP) | VAF 39/91 reads (43%) | catalogued as COSV65076887; called by muse, mutect2, varscan2
- ACSS1 | c.398A>C p.D133A | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV60220239; called by muse, mutect2, varscan2
- ADCY2 | c.1157T>C p.V386A | Missense Mutation (SNP) | VAF 92/416 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57872513; called by muse, mutect2, varscan2
- AHNAK2 | c.15786C>A p.S5262R | Missense Mutation (SNP) | VAF 158/473 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV60915308; called by muse, mutect2, varscan2
- AKNA | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 60/112 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56312599; called by muse, mutect2, varscan2
- ALMS1 | c.8933A>G p.D2978G | Missense Mutation (SNP) | VAF 118/353 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as rs1420360291, COSV52509862; called by muse, mutect2, varscan2
- AMY2B | c.1275T>A p.Y425* | Nonsense Mutation (SNP) | VAF 43/407 reads (11%) | catalogued as COSV63715266; called by muse, mutect2, varscan2
- ANKRD30A | c.3949G>C p.E1317Q (on ENST00000611781; = p.E1261Q on NM_052997.2) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.813); catalogued as COSV64610112; called by muse, mutect2
- ANXA4 | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67848272, COSV67848807; called by muse, mutect2, varscan2
- ARHGEF5 | c.2536G>A p.D846N | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV50210298; called by muse, mutect2, varscan2
- ATP10A | c.2912G>A p.S971N | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV63517348; called by muse, mutect2, varscan2
- ATP2C1 | c.1124T>G p.V375G | Missense Mutation (SNP) | VAF 200/725 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV60756421; called by muse, mutect2, varscan2
- BAIAP3 | c.737A>C p.K246T | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60980009; called by muse, mutect2, varscan2
- C6 | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54710158, COSV54710618; called by muse, mutect2, varscan2
- CAVIN4 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 25/131 reads (19%) | catalogued as COSV56867202; called by muse, mutect2, varscan2
- CCKAR | c.982C>G p.P328A | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55161459; called by muse, mutect2
- CDC42EP4 | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV59962830; called by muse, mutect2
- CEP135 | c.3340A>T p.M1114L | Missense Mutation (SNP) | VAF 87/490 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV57260009; called by muse, mutect2, varscan2
- COL7A1 | c.7423G>A p.G2475R | Missense Mutation (SNP) | VAF 74/121 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60395219; called by muse, mutect2, varscan2
- CTTN | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57232282; called by muse, mutect2, varscan2
- CWF19L2 | c.1055A>T p.N352I | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV56512528; called by muse, mutect2, varscan2
- CYBA | c.287+1G>T p.X96_splice | Splice Site (SNP) | VAF 11/114 reads (10%) | catalogued as CS101777, CS920743, COSV99879675; called by muse, mutect2, varscan2
- DCHS1 | c.7001C>T p.T2334M | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs753548138, COSV55035575; called by muse, mutect2, varscan2
- DEAF1 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 98/254 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs747111818, COSV58607073; called by muse, mutect2, varscan2
- DIAPH3 | c.1049C>T p.T350I (on ENST00000400324 / NM_001042517.2; = p.T87I on NM_030932.3) | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV57370575; called by muse, mutect2, varscan2
- DLX5 | c.777G>C p.W259C | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV56032494; called by muse, mutect2, varscan2
- DMBT1 | c.6023G>A p.S2008N (on ENST00000338354 / NM_001377530.1; = p.S1251N on NM_004406.3) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.883); catalogued as rs757677103, COSV57543790; called by muse, mutect2, varscan2
- DMBX1 | c.481C>A p.Q161K | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT tolerated (0.68); PolyPhen benign (0.05); catalogued as COSV63602003; called by muse, varscan2
- DOCK2 | c.4772T>A p.V1591E | Missense Mutation (SNP) | VAF 153/229 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV56958618; called by muse, mutect2, varscan2
- EPHB1 | c.1398C>G p.D466E | Missense Mutation (SNP) | VAF 78/275 reads (28%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.887); catalogued as COSV101212496; called by mutect2, varscan2
- EPHB4 | c.2571G>A p.W857* | Nonsense Mutation (SNP) | VAF 12/323 reads (4%) | catalogued as rs953048390, COSV62268835; called by muse, mutect2
- ESR1 | c.512A>T p.K171M | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV52790808; called by muse, mutect2, varscan2
- EXTL1 | c.1675C>G p.H559D | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV65332703; called by muse, mutect2, varscan2
- FAM71C | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.817); catalogued as rs751524661, COSV60943249; called by muse, mutect2, varscan2
- FAP | c.1211C>T p.T404I | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV51861808; called by muse, mutect2, varscan2
- FCAR | c.638T>A p.L213H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62029642; called by muse, mutect2, varscan2
- FEZF2 | c.880C>G p.R294G | Missense Mutation (SNP) | VAF 58/97 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51862953, COSV51863470; called by muse, mutect2, varscan2
- FLG2 | c.4340A>G p.H1447R | Missense Mutation (SNP) | VAF 281/754 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV66168676; called by muse, mutect2, varscan2
- FTHL17 | c.260G>T p.R87M | Missense Mutation (SNP) | VAF 70/99 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV63266932; called by muse, mutect2, varscan2
- FZD8 | c.1203G>T p.L401F | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs377031138, COSV65967890; called by muse, mutect2, varscan2
- GALNT13 | c.384G>A p.W128* | Nonsense Mutation (SNP) | VAF 60/119 reads (50%) | catalogued as COSV67221080; called by muse, mutect2, varscan2
- GALNT17 | c.52G>T p.V18L | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as COSV61162274; called by muse, mutect2, varscan2
- GAS7 | c.1152G>A p.M384I (on ENST00000432992 / NM_201433.2; = p.M244I on NM_003644.3) | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV60436425; called by muse, mutect2, varscan2
- GHR | c.1669C>G p.Q557E | Missense Mutation (SNP) | VAF 63/108 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50112590; called by muse, mutect2, varscan2
- HBG2 | c.93-1G>T p.X31_splice | Splice Site (SNP) | VAF 47/239 reads (20%) | catalogued as COSV100400534; called by muse, mutect2, varscan2
- HCN1 | c.2140G>T p.A714S | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs775543627, COSV57495256; called by muse, mutect2, varscan2
- IGKV6D-21 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 110/188 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs753016861; called by muse, mutect2, varscan2
- IRX1 | c.1419C>G p.I473M | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV57359476, COSV57359559; called by muse, mutect2, varscan2
- JKAMP | c.876G>T p.L292F (on ENST00000554271 / NM_001284201.1; = p.L278F on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/225 reads (34%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.906); catalogued as COSV54199478; called by muse, mutect2, varscan2
- KCNQ2 | c.1070A>G p.H357R | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.135); catalogued as rs926865634, COSV60434013; called by muse, mutect2, varscan2
- KCNQ3 | c.1814T>A p.V605E | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as COSV66470758; called by muse, mutect2, varscan2
- KCTD8 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV63589179; called by muse, mutect2, varscan2
- KDM5A | c.3721C>T p.P1241S | Missense Mutation (SNP) | VAF 98/212 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV66992386; called by muse, mutect2, varscan2
- KEAP1 | c.1252G>T p.V418L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV50281594, COSV50283871; called by muse, mutect2, varscan2
- KIF2B | c.854A>T p.Q285L | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV52130509, COSV99275925; called by muse, mutect2, varscan2
- KIRREL2 | c.1802A>G p.N601S | Missense Mutation (SNP) | VAF 88/292 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52876383; called by muse, mutect2, varscan2
- LAMA4 | c.267C>G p.N89K | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV54569660, COSV54570762; called by muse, mutect2, varscan2
- LIPG | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 103/267 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1008346648, COSV54295011; called by muse, mutect2, varscan2
- LRP10 | c.215+1G>T p.X72_splice | Splice Site (SNP) | VAF 42/121 reads (35%) | catalogued as COSV62078234; called by muse, mutect2, varscan2
- LRRN4 | c.1512C>A p.H504Q | Missense Mutation (SNP) | VAF 104/388 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66645289; called by muse, varscan2
- MCF2 | c.1879T>C p.Y627H | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58485276; called by muse, mutect2, varscan2
- MCM7 | c.1075G>T p.V359F | Missense Mutation (SNP) | VAF 291/753 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57996402; called by muse, mutect2, varscan2
- MLF1 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 96/169 reads (57%) | catalogued as COSV63033587; called by muse, mutect2, varscan2
- MMD2 | c.635T>C p.L212P (on ENST00000404774 / NM_001100600.2; = p.L188P on NM_198403.4) | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68660597; called by muse, mutect2, varscan2
- MOGAT2 | c.328del p.H110Mfs*30 | Frame Shift Del (DEL) | VAF 50/169 reads (30%) | catalogued as rs765298164; called by pindel, varscan2
- MTHFD1L | c.1839G>T p.M613I | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100944759; called by muse, mutect2, varscan2
- MTHFD1L | c.1840G>T p.A614S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100944760, COSV66226001; called by muse, mutect2, varscan2
- MTHFD1L | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66225338, COSV66225884; called by muse, mutect2
- MUC5B | c.6812C>A p.T2271N | Missense Mutation (SNP) | VAF 41/256 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV71592046; called by muse, mutect2, varscan2
- MXRA5 | c.1270C>A p.Q424K | Missense Mutation (SNP) | VAF 76/113 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV54234986, COSV54239582; called by muse, mutect2, varscan2
- MYH2 | c.2702C>A p.A901D | Missense Mutation (SNP) | VAF 140/307 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as rs769765489, COSV55438205; called by muse, mutect2, varscan2
- NCKAP1L | c.1386C>A p.F462L | Missense Mutation (SNP) | VAF 104/190 reads (55%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.989); catalogued as COSV53206798, COSV53211572; called by muse, mutect2, varscan2
- NEK6 | c.420G>C p.Q140H | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV57217576; called by muse, varscan2
- NF1 | c.2767C>G p.L923V | Missense Mutation (SNP) | VAF 128/305 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.097); catalogued as COSV62203262; called by muse, mutect2, varscan2
- NKD2 | c.944G>C p.R315P | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375289481, COSV56890246; called by muse, mutect2, varscan2
- NMT2 | c.1180G>A p.G394S | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as rs201047504, COSV65382197; called by muse, mutect2, varscan2
- NOP56 | c.1763A>G p.H588R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1568545131, COSV61389960; called by muse, mutect2, varscan2
- NPHS2 | c.530A>C p.H177P | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV62635264; called by muse, mutect2, varscan2
- NPY5R | c.1094G>T p.S365I | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.5); catalogued as COSV58451963; called by muse, mutect2, varscan2
- NR5A2 | c.530C>A p.A177D (on ENST00000367362 / NM_205860.3; = p.A131D on NM_003822.5) | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV52650192; called by muse, mutect2, varscan2
- NRXN3 | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73584486; called by muse, mutect2, varscan2
- NUP205 | c.4550C>G p.S1517C | Missense Mutation (SNP) | VAF 13/330 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as COSV53659159; called by muse, mutect2
- NXT1 | c.204C>A p.S68R | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54782961, COSV54783292; called by muse, mutect2
- OGDHL | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV65102400; called by muse, mutect2, varscan2
- OR10A5 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 167/551 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as rs1365738285, COSV55054108; called by muse, mutect2, varscan2
- OR11G2 | c.327A>G p.I109M | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV62132304; called by muse, mutect2, varscan2
- OR2G2 | c.301T>A p.L101M | Missense Mutation (SNP) | VAF 93/301 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV60740528; called by muse, mutect2, varscan2
- OSBPL11 | c.1386G>T p.K462N | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV56174010; called by muse, mutect2, varscan2
- PCDH10 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52088545; called by muse, mutect2, varscan2
- PCDHB2 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 90/146 reads (62%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.168); catalogued as COSV50573323; called by muse, varscan2
- PCDHGA6 | c.1970C>A p.T657N | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs1453617614, COSV53947145; called by muse, mutect2, varscan2
- PKDCC | c.793C>A p.H265N | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV54306824; called by muse, mutect2
- PKHD1 | c.10200G>T p.M3400I | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64390072; called by muse, mutect2, varscan2
- PKHD1 | c.10199T>C p.M3400T | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV64390076; called by muse, mutect2, varscan2
- PLEC | c.9289A>C p.I3097L (on ENST00000322810 / NM_201380.4; = p.I2987L on NM_000445.5) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.401); catalogued as rs1554683505, COSV59635758; called by muse, mutect2, varscan2
- PLEKHA6 | c.2428G>A p.V810M | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs759317655, COSV55333709, COSV99692660; called by muse, mutect2, varscan2
- PODXL2 | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as rs995114880, COSV61065397; called by muse, mutect2
- POTEF | c.2066A>G p.N689S | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1167123196, COSV62541278; called by muse, mutect2, varscan2
- PRH2 | c.100+1G>A p.X34_splice | Splice Site (SNP) | VAF 70/214 reads (33%) | catalogued as COSV67171660; called by muse, varscan2
- PRR14L | c.5584G>A p.G1862R | Missense Mutation (SNP) | VAF 196/316 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57884393; called by muse, mutect2, varscan2
- PSEN1 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 176/379 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56194501; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.685G>C p.D229H (on ENST00000421990 / NM_001136042.2; = p.D211H on NM_025267.3) | Missense Mutation (SNP) | VAF 195/529 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64182965; called by muse, mutect2, varscan2
- PXDN | c.2912T>C p.F971S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53233875; called by muse, mutect2
- PYGO2 | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV63756978; called by muse, mutect2, varscan2
- RHOBTB2 | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as rs144645186; called by muse, mutect2, varscan2
- RNASE3 | c.187C>A p.R63S | Missense Mutation (SNP) | VAF 130/281 reads (46%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.462); catalogued as COSV58959508, COSV58960113; called by muse, mutect2, varscan2
- RP1 | c.375del p.W127Gfs*16 | Frame Shift Del (DEL) | VAF 36/90 reads (40%) | catalogued as COSV55112273, COSV55113855; called by mutect2, varscan2
- SEMA6D | c.1513A>G p.S505G | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV60377335; called by muse, mutect2, varscan2
- SERPINB8 | c.1055C>A p.P352H | Missense Mutation (SNP) | VAF 20/281 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54639554; called by muse, mutect2
- SLC25A18 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs1362544934, COSV59408318; called by muse, mutect2, varscan2
- SLC34A2 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV65941483; called by muse, mutect2, varscan2
- SLC6A15 | c.1680G>T p.M560I | Missense Mutation (SNP) | VAF 95/176 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57023735; called by muse, mutect2, varscan2
- SPATA18 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.776); catalogued as COSV54644577; called by muse, mutect2, varscan2
- SPATA2 | c.622T>G p.S208A | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56866630; called by muse, mutect2, varscan2
- SPTA1 | c.6277G>T p.A2093S | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs1235629392, COSV63753003, COSV63755500; called by muse, mutect2, varscan2
- ST18 | c.1454C>A p.S485Y | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV52494174; called by muse, mutect2, varscan2
- STARD13 | c.812C>A p.A271D (on ENST00000336934 / NM_001243476.3; = p.A153D on NM_052851.3) | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV55230852; called by muse, varscan2
- SYNDIG1 | c.32T>A p.L11Q | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV65234993; called by muse, mutect2
- SYNDIG1L | c.443A>G p.E148G | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59047486; called by muse, mutect2
- SYNE1 | c.11147C>T p.S3716F (on ENST00000367255 / NM_182961.4; = p.S3701F on NM_033071.3) | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); catalogued as COSV54980610; called by muse, mutect2, varscan2
- TAS2R60 | c.491A>T p.H164L | Missense Mutation (SNP) | VAF 116/344 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.468); catalogued as COSV60330834; called by muse, mutect2, varscan2
- TBC1D32 | c.2696C>G p.P899R | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51543293; called by muse, mutect2, varscan2
- TCAIM | c.817C>G p.R273G | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.569); catalogued as COSV61240947, COSV61241898; called by muse, mutect2
- TCHH | c.4867G>A p.E1623K | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.312); catalogued as rs752069494, COSV64274769; called by muse, mutect2
- TCHP | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 28/154 reads (18%) | catalogued as COSV57165013, COSV57165553; called by muse, mutect2, varscan2
- TECTA | c.2000C>A p.A667D | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.8); catalogued as COSV50707657; called by muse, mutect2
- THRAP3 | c.1724C>G p.S575C | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as COSV63567788; called by muse, mutect2, varscan2
- TLK2 | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58300143; called by muse, mutect2, varscan2
- TRAPPC9 | c.3232C>T p.H1078Y | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs1467454222, COSV66899551; called by muse, mutect2
- TRPM7 | c.1945A>G p.M649V | Missense Mutation (SNP) | VAF 89/213 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs757469480, COSV57916370; called by muse, mutect2, varscan2
- TRPV3 | c.2357C>T p.P786L | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.024); catalogued as rs766763281, COSV56791393; called by muse, mutect2, varscan2
- TTC21A | c.2962C>A p.P988T | Missense Mutation (SNP) | VAF 58/90 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV57185030; called by muse, mutect2, varscan2
- TTC21A | c.2963C>A p.P988Q | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV57185039; called by muse, mutect2, varscan2
- TTN | c.39790A>G p.R13264G (on ENST00000591111; = p.R5840G on NM_003319.4) | Missense Mutation (SNP) | VAF 71/120 reads (59%) | PolyPhen benign (0.079); catalogued as COSV60059578; called by muse, mutect2, varscan2
- TXNDC9 | c.430C>A p.P144T | Missense Mutation (SNP) | VAF 101/362 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51811400, COSV51811926; called by muse, mutect2, varscan2
- UNC13C | c.2173G>A p.G725S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52872803; called by muse, mutect2, varscan2
- USF3 | c.1344G>C p.Q448H | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV57072672; called by muse, mutect2, varscan2
- USP29 | c.529G>T p.V177L | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV54142578; called by muse, mutect2, varscan2
- USP6NL | c.2309C>T p.A770V | Missense Mutation (SNP) | VAF 160/252 reads (63%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs778624638, COSV53211380; called by muse, mutect2, varscan2
- VRK3 | c.140G>C p.G47A | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.787); catalogued as COSV57465701; called by muse, mutect2, varscan2
- WDR17 | c.92T>A p.V31E | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54574062; called by muse, mutect2, varscan2
- WDR17 | c.3677A>T p.D1226V | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV54574077; called by muse, mutect2, varscan2
- WHRN | c.1070A>G p.K357R | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.816); catalogued as COSV54330646; called by muse, mutect2, varscan2
- WIPF1 | c.889A>G p.T297A | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV55814556; called by muse, mutect2, varscan2
- XIRP1 | c.1448T>C p.V483A | Missense Mutation (SNP) | VAF 19/233 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV61138484; called by muse, mutect2
- ZNF486 | c.11C>A p.P4H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV58719130; called by muse, mutect2, varscan2
- ZNF518A | c.3748A>G p.T1250A | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV60151416; called by muse, mutect2
- ZNF536 | c.2139C>G p.D713E | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV62824201; called by muse, mutect2, varscan2
- ZNF618 | c.584A>G p.K195R (on ENST00000374126 / NM_001318042.2; = p.K163R on NM_133374.2) | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55921269; called by muse, mutect2, varscan2
- ZNF831 | c.2942G>T p.G981V | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.785); catalogued as COSV64040194; called by muse, mutect2, varscan2
- ARID1A | c.3147_3154del p.D1050Sfs*52 | Frame Shift Del (DEL) | VAF 48/118 reads (41%) | called by mutect2, pindel, varscan2
- IGKJ5 | c.24del p.R9Hfs*? | Frame Shift Del (DEL) | VAF 44/132 reads (33%) | called by mutect2, varscan2
- IGLV3-12 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- KCTD16 | c.528_529insT p.G177Wfs*35 | Frame Shift Ins (INS) | VAF 50/102 reads (49%) | called by mutect2, pindel, varscan2
- KPNA4 | c.159dup p.E54* | Frame Shift Ins (INS) | VAF 49/231 reads (21%) | called by mutect2, pindel, varscan2
- MDN1 | c.12707_12717del p.L4236Pfs*9 | Frame Shift Del (DEL) | VAF 29/93 reads (31%) | called by mutect2, pindel, varscan2
- PPFIA2 | c.3767C>A p.S1256* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- ABCA2 | c.3813A>T p.P1271= (on ENST00000614293; = p.P1241= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/120 reads (33%) | catalogued as rs1417396706, COSV55801173; called by muse, mutect2, varscan2
- ADGRL1 | c.807C>T p.D269= (on ENST00000340736 / NM_001008701.3; = p.D264= on NM_014921.5) | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV61564700; called by muse, mutect2, varscan2
- ANPEP | c.1077G>A p.L359= | Silent (SNP) | VAF 68/162 reads (42%) | catalogued as COSV55591476; called by muse, varscan2
- ARHGEF10 | c.504C>T p.P168= (on ENST00000398564; = p.P144= on NM_014629.4) | Silent (SNP) | VAF 34/136 reads (25%) | catalogued as rs758217784, COSV50642988; called by muse, mutect2, varscan2
- BMT2 | c.12G>T p.G4= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs750221694, COSV51776695; called by muse, mutect2, varscan2
- CANT1 | c.1110C>A p.V370= | Silent (SNP) | VAF 51/134 reads (38%) | catalogued as COSV56605550; called by muse, mutect2, varscan2
- CARMIL3 | c.565C>A p.R189= | Silent (SNP) | VAF 46/413 reads (11%) | catalogued as rs755838540, COSV57726362; called by muse, mutect2, varscan2
- CCDC116 | c.825G>A p.E275= | Silent (SNP) | VAF 56/338 reads (17%) | catalogued as COSV53037223, COSV53037286; called by muse, mutect2, varscan2
- CD79B | c.531C>A p.I177= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV50077307; called by muse, mutect2, varscan2
- CFAP69 | c.2544G>T p.T848= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV60185831; called by muse, mutect2, varscan2
- CHPF | c.1317G>A p.P439= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as rs1426234114, COSV60534735; called by muse, mutect2, varscan2
- CYP2F1 | c.528C>A p.S176= | Silent (SNP) | VAF 82/254 reads (32%) | catalogued as COSV58527448; called by muse, mutect2, varscan2
- DCC | c.336G>A p.E112= | Silent (SNP) | VAF 52/175 reads (30%) | catalogued as COSV59102516; called by muse, mutect2, varscan2
- DIMT1 | c.564A>T p.L188= | Silent (SNP) | VAF 69/107 reads (64%) | catalogued as COSV52233672; called by muse, mutect2, varscan2
- DNAAF5 | c.1344C>A p.P448= | Silent (SNP) | VAF 73/201 reads (36%) | catalogued as COSV52414780, COSV52416810; called by muse, mutect2, varscan2
- DSC2 | c.1653A>G p.A551= | Silent (SNP) | VAF 121/358 reads (34%) | catalogued as rs1021990449, COSV51864584; called by muse, mutect2, varscan2
- ESR1 | c.513G>A p.K171= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as COSV52790817; called by muse, mutect2, varscan2
- FCN2 | c.165G>T p.L55= | Silent (SNP) | VAF 39/215 reads (18%) | catalogued as COSV52476969; called by muse, mutect2, varscan2
- GALNT17 | c.819C>G p.P273= | Silent (SNP) | VAF 132/430 reads (31%) | catalogued as COSV61162284, COSV61167321; called by muse, mutect2, varscan2
- GMPS | c.1836G>T p.P612= | Silent (SNP) | VAF 94/338 reads (28%) | catalogued as COSV55809436; called by muse, mutect2, varscan2
- GTF2E1 | c.63G>A p.V21= | Silent (SNP) | VAF 223/379 reads (59%) | catalogued as rs779528779, COSV52204278; called by muse, mutect2, varscan2
- HNF4G | c.246A>T p.V82= (on ENST00000354370 / NM_001330561.2; = p.V129= on NM_004133.5) | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV62965548, COSV62968567; called by muse, mutect2, varscan2
- INSIG1 | c.177G>T p.A59= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV60920355; called by muse, mutect2, varscan2
- LONRF2 | c.1386G>C p.T462= | Silent (SNP) | VAF 48/184 reads (26%) | catalogued as COSV66540605; called by muse, mutect2, varscan2
- MUC5B | c.9270C>A p.T3090= | Silent (SNP) | VAF 41/115 reads (36%) | catalogued as COSV71592047; called by muse, mutect2, varscan2
- MYO6 | c.1965G>C p.L655= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV64118987; called by muse, mutect2, varscan2
- NOCT | c.1089C>T p.T363= | Silent (SNP) | VAF 39/122 reads (32%) | catalogued as COSV54936024; called by muse, mutect2, varscan2
- OR4A47 | c.492C>A p.L164= | Silent (SNP) | VAF 164/403 reads (41%) | catalogued as COSV71444945; called by muse, mutect2, varscan2
- OR4N5 | c.474A>T p.V158= | Silent (SNP) | VAF 119/401 reads (30%) | catalogued as COSV61320537; called by muse, mutect2, varscan2
- PCDHB13 | c.573A>G p.K191= | Silent (SNP) | VAF 52/95 reads (55%) | catalogued as COSV53396513; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1677C>G p.L559= | Silent (SNP) | VAF 218/566 reads (39%) | catalogued as COSV50249392; called by muse, mutect2, varscan2
- RAET1G | c.660C>A p.A220= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV66274357; called by muse, mutect2, varscan2
- RP1 | c.879T>G p.S293= | Silent (SNP) | VAF 8/184 reads (4%) | catalogued as COSV55116651; called by muse, mutect2
- SCAF8 | c.2856C>T p.I952= | Silent (SNP) | VAF 173/424 reads (41%) | catalogued as COSV65791701; called by muse, mutect2, varscan2
- SLC33A1 | c.120G>A p.L40= | Silent (SNP) | VAF 24/196 reads (12%) | catalogued as COSV63947129; called by muse, mutect2, varscan2
- SLITRK4 | c.1989C>A p.S663= | Silent (SNP) | VAF 211/275 reads (77%) | catalogued as COSV62023883; called by muse, varscan2
- SPRYD3 | c.15G>C p.R5= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as COSV56853799; called by muse, mutect2, varscan2
- SPTA1 | c.6276G>T p.L2092= | Silent (SNP) | VAF 62/146 reads (42%) | catalogued as COSV63753004; called by muse, mutect2, varscan2
- TNFSF10 | c.375C>T p.H125= | Silent (SNP) | VAF 15/312 reads (5%) | catalogued as COSV53843325; called by muse, mutect2
- TTN | c.25158G>T p.L8386= (on ENST00000591111; = p.L7459= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 248/363 reads (68%) | catalogued as COSV60059626; called by muse, mutect2, varscan2
- UBE2NL | c.381G>A p.V127= | Silent (SNP) | VAF 140/156 reads (90%) | called by muse, mutect2, varscan2
- XRCC6 | c.60A>G p.Q20= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as COSV54354450; called by muse, mutect2, varscan2
- ZIM2 | c.1008C>T p.T336= | Silent (SNP) | VAF 66/155 reads (43%) | catalogued as rs1476709770, COSV55633410; called by muse, mutect2, varscan2
- ZNF423 | c.3747C>A p.A1249= (on ENST00000563137 / NM_001379286.1; = p.A1241= on NM_015069.4) | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV52188699; called by muse, mutect2, varscan2
- SNORD115-7 | n.23G>T | RNA (SNP) | VAF 104/306 reads (34%) | called by muse, mutect2, varscan2
